Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A93F, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A93F-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Consultation Report

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: F

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Accession #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Specimen(s) Received

1. Lymph-Node: ST7 Subcarinal
2. Lymph node: Diaphragmatic nodes ST15
3. Lymph node: Aorto-pulmonary ST5
4. Lymph node: Inf.pulm. ligament ST9L
5. Lymph node: Para esophageal ST8
6. Lymph node: Right upper paratracheal node
7. Lymph node: Lt low paratracheal ST4L
8. Lymph node: Lt up paratracheal ST2L
9. Lymph node: Lt recurrent nerve lymph node
10. Lymph node: Lt gastric lymph node
11. Lymph node: Stn 19 splenic nodes
12. Lymph node: cervical lymph node
13. Thoracic esophagus and proximal stomach with esophageal margin
14. Lymph node: Subcarinal ST7
15. Lymph node: Para esophageal ST8
16. Lymph node: Diaphragmatic nodes ST15
17. Lymph node: Lt gastric nodes ST17
18. Lymph node: Station 19
19. Lymph node: Station 20
20. Esophagus: Final esophageal margin
21. Surgical Waste

ICD-O-3

Carcinoma, squamous cell NOS
8070/3
Site Esophagus, distal third
C15.5

JJ 4/18/14

Diagnosis

1. **Lymph-Node, ST7 Subcarinal:**
Regional lymph nodes (5), negative for malignancy (0/5)
2. **Lymph node, Diaphragmatic nodes ST15:**
Regional lymph nodes (4), negative for malignancy (0/4)
3. **Lymph node, Aorto-pulmonary ST5:**
Regional lymph nodes (2), negative for malignancy (0/2)
4. **Lymph node, Inferior pulmonary ligament ST9L:**
Regional lymph nodes (3), negative for malignancy (0/3)
5. **Lymph node, Para esophageal ST8:**
Fibrofatty tissue, negative for malignancy

[page 2 of 6]
- 6. Lymph node, Right upper paratracheal node:**
Regional lymph node (1), negative for malignancy (0/1)
- 7. Lymph node, Left low paratracheal ST4L:**
Regional lymph nodes (1), negative for malignancy (0/1)
- 8. Lymph node, Left upper paratracheal ST2L:**
Regional lymph nodes (6), negative for malignancy (0/6)
- 9. Lymph node, left recurrent nerve lymph node:**
Regional lymph nodes (3), negative for malignancy (0/3)
- 10. Lymph node, left gastric lymph node:**
Fibrofatty tissue, negative for malignancy
- 11. Lymph node, STN 19 splenic nodes:**
Regional lymph nodes (1), negative for malignancy (0/1)
- 12. Lymph node, cervical lymph node:**
Fibrofatty tissue, negative for malignancy
- 13. Thoracic esophagus and proximal stomach with esophageal margin:**
Squamous cell carcinoma, pT2N0Mx – see synoptic for details
Fundic gland polyp, stomach
- 14. Lymph node, Subcarinal ST7:**
Regional lymph nodes (2), negative for malignancy (0/2)
- 15. Lymph node, Para esophageal ST8:**
Regional lymph nodes (2), negative for malignancy (0/2)
- 16. Lymph node, Diaphragmatic nodes ST15:**
Regional lymph nodes (2), negative for malignancy (0/2)
- 17. Lymph node, Left gastric nodes ST17:**
Regional lymph nodes (1), negative for malignancy (0/1)
- 18. Lymph node, Station 19:**
Regional lymph nodes (4), negative for malignancy (0/4)
- 19. Lymph node, Station 20:**
Regional lymph nodes (2), negative for malignancy (0/2)
- 20. Esophagus, Final esophageal margin:**
Negative for malignancy
- 21. Surgical Waste:**
No significant pathology (gross exam only)

Comment

Part 21

"THIS CASE HAS BEEN EXAMINED BY GROSS VISUAL EXAMINATION ONLY. NO MICROSCOPIC EXAMINATION HAS BEEN PERFORMED. IF THERE IS A CLINICAL INDICATION OR SUSPICION OF AN ABNORMALITY THAT WOULD REQUIRE ADDITIONAL STUDIES THEN THE SIGNING PATHOLOGIST (BELOW) SHOULD BE CONTACTED WITHIN ONE MONTH OF THE ISSUING OF THIS REPORT."

Synoptic Data

[page 3 of 6]
Surgical Pathology Consultation Report

Clinical History:	Not known: .
Specimen:	Esophagus Proximal stomach
Procedure:	Esophagogastrectomy
Primary Tumor Site:	Distal esophagus (lower thoracic esophagus)
Additional Sites Involved by Tumor:	Esophagogastric junction (EGJ)
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint lies in the distal esophagus and tumor involves the esophagogastric junction
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G1: Well differentiated
Tumor Size:	Cannot be determined: 2 lesions belong to one tumor, aggregate size is 6.5 cm x 4.6 cm
Microscopic Tumor Extension:	Tumor invades muscularis propria
Proximal Margin:	Uninvolved by invasive carcinoma Uninvolved by dysplasia
Distal Margin:	Uninvolved by invasive carcinoma Uninvolved by dysplasia
Circumferential (Adventitial) or Deep Margin:	Uninvolved by invasive carcinoma
	All Margin Status
	All margins uninvolved by invasive carcinoma
	Distance of invasive carcinoma from closest margin: 2 mm
	Closest margin: Circumferential
Treatment Effect:	Treatment history not known
Lymph-Vascular Invasion:	Not identified: .
Perineural Invasion:	Not identified: .
TNM Descriptors:	Not applicable: .
Primary Tumor (pT):	pT2: Tumor invades muscularis propria
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 39 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable: .

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

Esophageal Ca

Gross Description

1. The specimen labeled as "lymph node ST7 subcarinal", consists of 6 fragments of tan anthracotic tissue measuring from 1.0 x 0.4 x 0.4 cm up to 1.6 x 1.2 x 0.4 cm which are received in 10% neutral buffered formalin.

1A --1B -- a single fragment in each block

1C -- multiple individual fragments

2. The specimen labeled as "lymph node diaphragmatic ST15", consists of a tan fatty tissue fragment measuring 2.5 x 2.5 x 0.4 cm which are received in 10% neutral buffered formalin. No obvious lymph nodes can be grossly identified.

2A-specimen submitted in toto.

3. The specimen labeled as "lymph node aortopulmonary ST 5", consists of a single tan tissue fragment measuring 1.2 x 0.6 x 0.6 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty cut surface.

[page 4 of 6]
3A – specimen bisected and submitted in toto

4. The specimen labeled as "lymph node inferior pulmonary ligament ST9L", consists of a tan fatty tissue fragment measuring 1.6 x 1.1 x 0.6 cm which is received in 10% neutral buffered formalin. No obvious lymph nodes can be grossly identified.

4A – specimen bisected and submitted in toto

5. The specimen labeled as "lymph node paraesophageal ST 8", consists of two tan fatty tissue fragments measuring 2.5 x 1.2 with 0.4 cm and 2.5 x 2.0 x 0.6 cm which are received in 10% neutral buffered formalin. No obvious lymph nodes can be grossly identified.

5A – larger fragment serially sectioned submitted in toto

5B – smaller fragment submitted in toto

6. The specimen labeled as "lymph node right upper paratracheal", consists of a tan fatty lymph node measuring 1.9 x 1.4 x 0.8 cm which is received in 10% neutral buffered formalin.

6A – specimen bisected and submitted in toto

7. The specimen labeled as "lymph node left low paratracheal ST4L", consists of a tan fragment of adipose measuring 2.8 x 1.5 x 0.4 cm which is received in 10% neutral buffered formalin. No obvious lymph nodes can be grossly identified.

7A-specimen submitted in toto.

8. The specimen labeled as "lymph node left upper paratracheal ST2L.", consists of 7 tan fragments of tissue measuring from 0.4 x 0.3 x 0.3 up to 2.0 x 1.0 x 0.8 cm which are received in 10% neutral buffered formalin.

8A – single fragment bisected and submitted in toto

8B – remaining fragments submitted in toto

9. The specimen labeled as "left recurrent nerve lymph node", consists of a tan fatty tissue fragment measuring 2.0 x 1.0 x 0.8 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty cut surface.

9A – specimen bisected and submitted in toto

10. The specimen labeled as "left gastric lymph node", consists of a fragment of adipose measuring 1.5 x 1.0 x 0.3 cm which is received in 10% neutral buffered formalin. No obvious lymph nodes can be grossly identified.

10A-specimen submitted in toto.

11. The specimen labeled as "station 19 splenic node", consists of a tan fatty lymph node measuring 1.3 x 1.0 x 0.3 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty cut surface.

11A – specimen bisected and submitted in toto

12. The specimen labeled as "cervical lymph node", consists of a tan anthracotic tissue fragment measuring 1.5 x 0.6 x 0.5 cm which is received in 10% neutral buffered formalin. Sectioning reveals an anthracotic cut surface.

12A – specimen bisected and submitted in toto

13. RESECTION SPECIMEN: Distal esophagus and proximal stomach

FIXATION: Received fresh and transferred to 10% neutral buffered formalin

DIMENSIONS:

Length along lesser curvature: 2.4 cm

Length along greater curvature: 6.7 cm

Circumference of distal gastric margin: 11.5 cm

Circumference of proximal gastric margin: 3.2 cm

Length of tubular esophagus: 12.5 cm

Width of tubular esophagus: 3.2 cm

The external surface of the esophagus is painted with silver nitrate.

TUMOR

LOCATION:

There are 3 areas of interest grossly identified on the esophageal and gastric mucosa.

[page 5 of 6]
Mass 1: There is a tan ulcerated ill-defined mass on the esophageal mucosa measuring 4.8 cm in length and 3.0-cm in diameter. The mass occupies 75% of the circumference of the esophagus and there is a cobblestoned esophageal mucosa continuous with the mass that extends over an area of 6.5-cm. Sectioning of the mass reveals a thickness of 1.2-cm.

The mass approaches the margins as follows:

Proximal: 1.3 cm

Distal: 9.4 cm

Painted esophageal external surface: 0.2

Mass 2: There is a tan friable mass just proximal to the GE junction measuring 1.7-cm in length by 1.6-cm in diameter. The mass occupies 50% of the circumference of the esophagus and there is approximately 0.7-cm of unremarkable esophageal mucosa separating the two mass lesions. Sectioning of the mass reveals a thickness of 0.6-cm.

The mass approaches the margins as follows:

Proximal: 10-cm

Distal: 4.3-cm

Painted esophageal external surface: 0.6-cm

Polyp: There is a tan polyp adjacent to the distal gastric excision margin measuring 0.5 x 0.4 x 0.2 cm.

- **PERFORATION:** No perforations are grossly identified

ESTIMATED DEPTH OF INVASION: Mass 1 appears to invade through the muscularis but Mass 2 does not invade through the muscularis.

LESIONS IN NONCANCEROUS STOMACH: No other lesions are grossly identified

LYMPH NODES: There is little to no appreciable periesophageal and perigastric fat grossly identified and no lymph nodes can be grossly identified.

The proximal esophageal excision margin is submitted for intraoperative consult and further submitted for permanent processing.

Representative tissue is stored frozen

Photographs are taken

Representative Sections:

13A -- proximal surgical excision margin submitted en face

13B -- 13C -- distal surgical excision margin submitted en face

13 D -- 13 H. -- a strip of tissue submitted from the proximal margin to the GE junction with the proximal edge of each piece painted with green ink including Mass 1 and Mass 2.

13 I -- 13 L. -- further representative sections of mass 1

13M -- 13R -- remainder of mass 2 and GE junction submitted in toto

13S -- polyp at distal margin submitted in toto

14. The specimen labeled as "lymph node subcarinal ST 7", consists of a tan fatty tissue fragment measuring 2.5 x 1.2 x 0.6 cm which is received in 10% neutral buffered formalin. The specimen is bisected revealing a tan anthracotic cut surface.

14 A. -- specimen submitted in toto

15. The specimen labeled as "lymph node periesophageal ST8", consists of 2 tan fatty lymph nodes measuring 0.6 and 0.8 cm in diameter which are received in 10% neutral buffered formalin.

15 A -specimen submitted in toto.

16. The specimen labeled as "lymph node diaphragmatic nodes ST 15", consists of a fragment of adipose measuring 2.8 x 2.0 x 0.4 cm which is received in 10% neutral buffered formalin. No obvious lymph nodes can be grossly identified.

16 A. -specimen submitted in toto.

[page 6 of 6]
Surgical Pathology Consultation Report

17. The specimen labeled as "lymph node left gastric nodes ST 17", consists of a fragment of adipose measuring 6.0 x 4.0 x 1.5 cm which is received in 10% neutral buffered formalin. Examination reveals the presence of a single tan fatty lymph node measuring 1.8 x 1.0 x 0.8 cm which is received in 10% neutral buffered formalin.

17A — lymph node bisected and submitted in toto

18. The specimen labeled as "lymph node station 19", consists of a fragment of adipose measuring 4.0 x 3.5 x 1.5 cm which is received in 10% neutral buffered formalin. Examination reveals the presence of two tan lymph nodes measuring 0.6 and 0.8 cm diameter.

18A — lymph nodes submitted in toto

19. The specimen labeled as "lymph node station 20", consists of a fragment of adipose measuring 5.5 x 3.5 x 2.5 cm which is received in 10% neutral buffered formalin. Examination reveals the presence of 2 tan fatty lymph nodes measuring 0.6 and 0.8 cm diameter.

19A —specimen submitted in toto.

20. The specimen labeled as "final esophageal margin", consists of a tan tissue fragment measuring 2.5 x 0.6 x 0.4 cm which is received in 10% neutral buffered formalin.

20A —specimen submitted in toto.

21. The specimen container labeled with the patient's name and as "surgical Waste", contains 1 piece of tissue in 10% buffered formalin. The tissue consists of a single fragment of adipose measuring 12 x 4.5 x 2.5 cm which is received in 10% neutral buffered formalin. No gross abnormalities are identified.

No material is submitted for histologic evaluation.

Quick Section Diagnosis

13. Esophagus proximal margin, en face: Negative for carcinoma

Time reported to surgeon:

Source: NCI Genomic Data Commons file bcd6b786-fac1-4082-b98e-c0f69d13f6a8 (TCGA-JY-A93F.666D9217-831B-46FF-B58A-55185B0656C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).